TCGA case TCGA-G3-AAV7 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d259f26-3bef-4fe4-948b-495183f5f8be

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 38 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 39.0 years (14,229 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 361 days; Child pugh classification: A; Ishak fibrosis score: 5 - Nodular Formation and Incomplete Cirrhosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 92 days; Disease response: Tumor Free.
- Days to follow up: 361 days; Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets 179 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.1].
- Creatinine 1.1 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.4].
- Total Bilirubin 0.9 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.4].
- Albumin 4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.3; Blood test normal range upper: 4.8].
- Alpha Fetoprotein 3 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 10].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 165 cm; BMI: 21.3.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Surface Antibody / HBV DNA.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G3-AAV7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-G3-AAV7-01A-01-TSA: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 2; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G3-AAV7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G3-AAV7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple; Hepatic inflammation adj tissue: Mild; New tumor event diagnosis indicator: No.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: Hbv dna.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 361 days; disease-specific survival: no event (censored), 361 days; disease-free interval: no event (censored), 361 days; progression-free interval: no event (censored), 361 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G3-AAV7-01A-11D-A381-01): tumor purity 0.65, ploidy 1.73, whole-genome doublings 0.
